Gene-level copy-number profile of tumor specimen ALCH-AEDW-TTP1-A from ALCHEMIST case ALCH-AEDW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 53.3 years (19,461 days).
Specimen ALCH-AEDW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3947c47a-2ca2-4e9b-828a-8341f315fff4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEDW-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/a5084c30-8ce2-49f6-aeba-adfa4513522a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 515; copy number 1: 5,773; copy number 2: 28,386; copy number 3: 16,837; copy number 4: 4,956; copy number 5: 1,092; copy number 6: 797; copy number 7: 164; copy number 8: 364; copy number 9: 18; copy number 10: 5; copy number 11: 5; copy number 13: 3.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:170,178,681–170,179,660, 1 gene: AL596442.2.
- chr20:30,278,906–30,289,956, 2 genes: LINC01597, AL121762.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,448 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:149,129,638–149,752,495, 20 genes, copy number 7: HPS3, CP, CPHL1P, AC093001.1, TM4SF18, AC073522.1, TM4SF1, TM4SF1-AS1, AC108751.4, AC108751.2, AC108751.3, FKBP1AP4, AC108751.1, TM4SF4, AC108751.5, WWTR1, RNU6-1098P, WWTR1-IT1, WWTR1-AS1, COMMD2.
- chr4:139,256,657–139,454,034, 8 genes, copy number 5 (within-gene range 4–5): RNU6-1074P, MGARP, NDUFC1, NAA15, RNU6-1214P, AC097376.3, AC097376.2, AC097376.1.
- chr7:63,044,827–158,956,747, 1,893 genes, copy number 5–11 (within-gene range 3–11) (broad region; genes not listed).
- chr9:61,190,003–61,627,683, 9 genes, copy number 5: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D.
- chr9:61,665,579–61,887,084, 5 genes, copy number 5–13: AL935212.2, RN7SL722P, AL391987.4, AL391987.3, Y_RNA.
- chr9:63,703,065–63,762,824, 5 genes, copy number 6: AL591438.2, CDRT15P7, AL772155.1, AL772155.2, MYO5BP3.
- chr9:135,546,126–138,253,217, 144 genes, copy number 5 (broad region; genes not listed).
- chr10:68,988,803–69,043,544, 1 gene, copy number 5 (within-gene range 3–5): KIFBP.
- chr10:69,022,778–69,023,866, 1 gene, copy number 5: ACTBP14.
- chr16:2,339,150–2,868,251, 51 genes, copy number 5 (within-gene range 1–5): ABCA17P, CCNF, AC106820.6, MIR6767, AC106820.3, AC106820.5, TEDC2, MIR6768, AC106820.2, NTN3, TBC1D24, AC106820.4, AC093525.2, ATP6V0C, AC093525.1, AC093525.8, AMDHD2, CEMP1, MIR3178, PDPK1, AC093525.6, AC093525.5, AC093525.7, AC093525.4, AC093525.3, AC093525.9, AC093525.10, AC141586.5, AC141586.3, AC141586.1, PDPK2P, AC141586.4, AC141586.2, ERVK13-1, KCTD5, AC092117.2, PRSS27, SRRM2-AS1, SRRM2, ELOB, AC092117.1, PRSS33, SNORA3C, PRSS41, PRSS21, EIF1P4, ZG16B, PRSS30P, PRSS22, AC003965.2, AC003965.1.
- chr16:4,803,203–18,598,328, 311 genes, copy number 6–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,585. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
